TCGA case TCGA-85-8048 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/90648a49-997b-418c-9724-bd1d216eb861

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 62.7 years (22,907 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 765 days (2.1 years); Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.

Follow-up (3 entries)
- Days to follow up: 26 days; Disease response: Tumor Free.
- Days to follow up: 765 days (2.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Other.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 50; Tobacco smoking onset year: 1960.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-85-8048-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.9; Shortest dimension: 0.3.
  Slide TCGA-85-8048-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 3; Percent necrosis: 4; Percent stromal cells: 33; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 2.
  Slide TCGA-85-8048-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 15; Percent necrosis: 3; Percent stromal cells: 22; Percent lymphocyte infiltration: 18; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 2.
- Sample TCGA-85-8048-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-85-8048-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Lower; Location lung parenchyma: Peripheral Lung; Pulmonary function test indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 765 days; disease-specific survival: no event (censored), 765 days; disease-free interval: no event (censored), 765 days; progression-free interval: no event (censored), 765 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-85-8048-01A-11D-2243-01): tumor purity 0.18, ploidy 1.89, whole-genome doublings 0.
